CCDI case PBCNBR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f29e2eab-d7cd-4fc6-a5a7-dc26ac28b2fe

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,806 days).

Biospecimens (3 samples)
- Sample 0DVSBP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVSBX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVSCA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
